Somatic mutation profile of tumor specimen TCGA-D8-A13Y-01A (aliquot TCGA-D8-A13Y-01A-11D-A10Y-09) from TCGA case TCGA-D8-A13Y, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 52.1 years (19,028 days).
Specimen TCGA-D8-A13Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acc64b15-2a13-40f9-837e-52559d54a19a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A13Y-10A (Blood Derived Normal), aliquot TCGA-D8-A13Y-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1ce52d4-fe04-44bf-bbcb-21d57fafed78

The open-access MAF lists 79 somatic variants for this specimen: 60 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 50, Silent 19, Frame Shift Del 5, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B4 | c.1060dup p.R354Pfs*132 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | catalogued as rs782357237; ClinVar: pathogenic; called by mutect2, varscan2
- ACE | c.987C>A p.F329L | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV52009825, COSV52014249; called by muse, mutect2, varscan2
- AMBP | c.76C>G p.P26A | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV54325947; called by muse, mutect2, varscan2
- APOLD1 | c.703G>A p.E235K (on ENST00000326765 / NM_001130415.2; = p.E204K on NM_030817.3) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs1234674220, COSV58734510; called by muse, mutect2, varscan2
- ASH1L | c.1475A>C p.K492T | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.981); catalogued as COSV64214772; called by muse, mutect2, varscan2
- ATP10B | c.1963G>A p.V655M | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as rs1484095183, COSV59148761; called by muse, mutect2, varscan2
- C1orf43 | c.370C>T p.P124S (on ENST00000368521 / NM_001297718.2; = p.P90S on NM_015449.4) | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as rs1279319938, COSV62967023; called by muse, mutect2, varscan2
- CENPO | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99569217; called by muse, mutect2
- CLK3 | c.913G>A p.E305K (on ENST00000395066 / NM_001130028.1; = p.E157K on NM_003992.4) | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.303); catalogued as COSV61415214; called by muse, mutect2, varscan2
- COL16A1 | c.4054G>A p.E1352K | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.824); catalogued as COSV54715243; called by muse, mutect2, varscan2
- CSNK2A2 | c.700T>A p.F234I | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99345523; called by muse, mutect2
- CUBN | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.305); catalogued as COSV64729127; called by muse, mutect2, varscan2
- DOK7 | c.880A>G p.T294A | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs143821601; called by muse, varscan2
- DSE | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 78/104 reads (75%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV59063366; called by muse, mutect2, varscan2
- ELL2 | c.1626G>C p.Q542H | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52985638; called by muse, mutect2, varscan2
- FNBP4 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.081); catalogued as COSV55452728; called by muse, mutect2, varscan2
- GPR12 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 94/122 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.407); catalogued as rs752179748, COSV67345035; called by muse, mutect2, varscan2
- HAUS5 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT tolerated (0.26); PolyPhen benign (0.186); catalogued as rs188926778; called by muse, mutect2, varscan2
- HGD | c.30T>G p.F10L | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.509); catalogued as COSV52202013; called by muse, mutect2, varscan2
- HMBS | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 75/85 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs757873631, COSV53830219; called by muse, mutect2, varscan2
- HTATSF1 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.013); catalogued as COSV54481955; called by muse, mutect2, varscan2
- IREB2 | c.2471C>T p.T824M | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs200306100, COSV51920429; called by muse, mutect2, varscan2
- KCNQ3 | c.1027T>A p.F343I | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66483729; called by muse, mutect2, varscan2
- KIF1B | c.3178G>A p.E1060K (on ENST00000377086 / NM_001365952.1; = p.E1014K on NM_015074.3) | Missense Mutation (SNP) | VAF 117/144 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV55817428; called by muse, mutect2, varscan2
- MED8 | c.482C>G p.S161* | Nonsense Mutation (SNP) | VAF 189/507 reads (37%) | catalogued as COSV51942701; called by muse, mutect2, varscan2
- MON1B | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 54/62 reads (87%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV50255054; called by muse, mutect2, varscan2
- MYH1 | c.4690C>T p.R1564C | Missense Mutation (SNP) | VAF 132/157 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs555367957, COSV56847943; called by muse, mutect2, varscan2
- NOBOX | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.035); catalogued as rs753930313, COSV56197660; called by muse, mutect2, varscan2
- OR5I1 | c.364T>A p.Y122N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs1192871873, COSV56889510; called by muse, mutect2, varscan2
- PCDH11X | c.3847G>A p.V1283M | Missense Mutation (SNP) | VAF 170/209 reads (81%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as rs1208717817, COSV53511323; called by muse, mutect2, varscan2
- PCDHA2 | c.2122T>A p.S708T | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as COSV65371782; called by muse, mutect2, varscan2
- PCDHA2 | c.2123C>A p.S708Y | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65371788; called by muse, mutect2, varscan2
- PCDHA5 | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV65355353; called by muse, mutect2, varscan2
- PREPL | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.906); catalogued as COSV53216602, COSV53219756; called by muse, mutect2, varscan2
- RAPSN | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.049); catalogued as COSV100100443; called by muse, mutect2
- RELN | c.4319G>T p.C1440F | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV59038204; called by muse, mutect2, varscan2
- RFX3 | c.581C>G p.A194G | Missense Mutation (SNP) | VAF 98/111 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV56526257; called by muse, mutect2, varscan2
- RYR1 | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62113188; called by muse, mutect2, varscan2
- SLC12A7 | c.1856C>G p.S619C | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53756911, COSV53763457; called by muse, mutect2, varscan2
- SLC25A32 | c.932G>A p.R311K | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV52569591; called by muse, mutect2, varscan2
- SLCO4C1 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60520734; called by muse, mutect2, varscan2
- TBKBP1 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 84/97 reads (87%) | catalogued as COSV64654729; called by muse, mutect2, varscan2
- TPSG1 | c.928C>G p.P310A | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.981); catalogued as COSV99327164; called by muse, mutect2
- TRIM48 | c.428G>A p.C143Y | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV70163495; called by muse, mutect2, varscan2
- TRPC4 | c.1798A>T p.M600L | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV59022077; called by muse, mutect2, varscan2
- TSEN2 | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 97/303 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as COSV53191345; called by muse, mutect2, varscan2
- TTK | c.2026A>G p.T676A | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57887339; called by muse, mutect2, varscan2
- UGT2B10 | c.1350T>A p.D450E | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV99608851; called by muse, mutect2
- VPS13A | c.600G>C p.E200D | Missense Mutation (SNP) | VAF 153/363 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.22); catalogued as COSV104421264, COSV62440617; called by muse, mutect2, varscan2
- ZNF41 | c.784C>G p.Q262E | Missense Mutation (SNP) | VAF 129/150 reads (86%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV100491835, COSV57445620; called by muse, mutect2, varscan2
- ZNF488 | c.574C>A p.L192M | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs966532272; called by muse, mutect2, varscan2
- ZNF560 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs757976367, COSV56865089; called by muse, mutect2, varscan2
- CSPG4 | c.2583_2607del p.T862Rfs*88 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- EPHX4 | c.833T>G p.I278S | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- H4C4 | c.117_147del p.R40Sfs*10 | Frame Shift Del (DEL) | VAF 88/182 reads (48%) | called by mutect2, pindel, varscan2
- MUC5B | c.1216_1220+20del p.X406_splice | Splice Site (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- OR52H1 | c.686del p.G229Afs*68 (on ENST00000322653; = p.G235Afs*68 on NM_001005289.1) | Frame Shift Del (DEL) | VAF 75/100 reads (75%) | called by mutect2, pindel*, varscan2
- POLB | c.319_320+9del p.X107_splice | Splice Site (DEL) | VAF 32/212 reads (15%) | called by mutect2, pindel, varscan2
- TEX37 | c.451_457del p.L151Cfs*11 | Frame Shift Del (DEL) | VAF 56/110 reads (51%) | called by mutect2, pindel, varscan2
- TP53 | c.412_427del p.A138Cfs*27 | Frame Shift Del (DEL) | VAF 43/56 reads (77%) | called by mutect2, pindel, varscan2
- ALPP | c.612G>T p.G204= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV67398297, COSV67398409; called by muse, mutect2, varscan2
- CYB5A | c.45G>A p.E15= | Silent (SNP) | VAF 127/305 reads (42%) | catalogued as COSV55023418; called by muse, mutect2, varscan2
- DCC | c.186C>T p.S62= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as rs767925738, COSV59084438; called by muse, mutect2, varscan2
- KATNA1 | c.330A>G p.P110= | Silent (SNP) | VAF 11/181 reads (6%) | catalogued as rs1363344603, COSV100168064; called by muse, mutect2
- MAP3K11 | c.1269G>A p.E423= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV58422142; called by muse, mutect2
- MMP16 | c.861G>A p.Q287= | Silent (SNP) | VAF 71/163 reads (44%) | catalogued as COSV54192821; called by muse, mutect2, varscan2
- MMRN1 | c.1743G>A p.L581= | Silent (SNP) | VAF 17/23 reads (74%) | catalogued as COSV53343545; called by muse, mutect2, varscan2
- NCAPD3 | c.535A>C p.R179= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as COSV101596381; called by muse, mutect2, varscan2
- OR8G5 | c.189C>T p.L63= | Silent (SNP) | VAF 170/201 reads (85%) | catalogued as rs1341295514, COSV100422714; called by muse, mutect2, varscan2
- OTULIN | c.567A>G p.K189= | Silent (SNP) | VAF 60/178 reads (34%) | catalogued as COSV52507450; called by muse, mutect2, varscan2
- PAK5 | c.1158C>G p.P386= | Silent (SNP) | VAF 93/214 reads (43%) | catalogued as rs1204009716, COSV62022559, COSV62039655; called by muse, mutect2, varscan2
- PAN2 | c.2895G>A p.L965= (on ENST00000425394 / NM_001127460.3; = p.L961= on NM_014871.5) | Silent (SNP) | VAF 83/352 reads (24%) | catalogued as COSV56265374; called by muse, mutect2, varscan2
- PHF14 | c.598C>T p.L200= | Silent (SNP) | VAF 79/193 reads (41%) | catalogued as COSV68857664; called by muse, mutect2, varscan2
- PLEC | c.7272C>T p.A2424= (on ENST00000322810 / NM_201380.4; = p.A2314= on NM_000445.5) | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV59704259; called by muse, mutect2, varscan2
- SOX5 | c.807C>T p.I269= | Silent (SNP) | VAF 94/199 reads (47%) | catalogued as COSV58619226, COSV58622818; called by muse, mutect2, varscan2
- SSX2IP | c.72A>G p.S24= | Silent (SNP) | VAF 44/71 reads (62%) | catalogued as COSV60554866; called by muse, mutect2, varscan2
- STX5 | c.273C>T p.R91= | Silent (SNP) | VAF 74/180 reads (41%) | catalogued as COSV53682393; called by muse, mutect2, varscan2
- TRMT11 | c.939C>T p.I313= | Silent (SNP) | VAF 80/348 reads (23%) | catalogued as COSV57674549; called by muse, mutect2, varscan2
- ZNF512B | c.2410C>T p.L804= | Silent (SNP) | VAF 112/121 reads (93%) | catalogued as rs112150897, COSV53879489; called by muse, mutect2, varscan2
